TCGA case TCGA-OR-A5JM — Adrenocortical Carcinoma (TCGA-ACC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fb54458d-c373-46c2-841e-82663e13efaa

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Australia; Age at index: 25 years; Vital status: Dead; Days to death: 562 days (1.5 years).

Diagnoses (2)
1. Adrenal cortical carcinoma (the primary disease): ICD-O-3 morphology code: 8370/3; ICD-10 code: C74.0; Tissue or organ of origin: Cortex of adrenal gland; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 25.6 years (9,359 days); Year of diagnosis: 2011; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Residual disease: R1; Ensat clinical m: M1; Ensat pathologic n: N0; Ensat pathologic stage: Stage IV; Ensat pathologic t: T4; Sites of involvement: Liver; Weiss assessment findings: Atypical Mitotic Figures / Cytoplasm presence <= to 25% / Diffuse Architecture / Invasion of Tumor Capsule / Mitotic Rate > 5/50 HPF / Necrosis / Nuclear Grade III or IV / Sinusoid Invasion / Venous Invasion; Weiss assessment score: 9.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 134 days; Days to treatment end: 196 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ketoconazole + Sunitinib; Days to treatment start: 378 days (1.0 years); Days to treatment end: 439 days (1.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mitotane; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Therapeutic target level: >14 mg/L.
2. Metastasis of diagnosis 1 (Adrenal cortical carcinoma), site: Liver. Age at diagnosis: 25.8 years (9,431 days); Days to diagnosis: 72 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Day 72 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 72 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 562 days (1.5 years); Disease response: With Tumor.
- Day 562 (within 3 months of surgery): Disease response: Biochemical Evidence of Disease.
- Imaging type: CT Scan; Imaging findings: Liver Involvement; Timepoint: Preoperative.

Molecular and laboratory tests
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 90.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factor method of diagnosis: Both Clinical and Biochemical Assessments; Risk factors: Cortisol Excess.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-OR-A5JM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-OR-A5JM-01A-01-TSA: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 17; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-OR-A5JM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-OR-A5JM-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: Yes; Tumor status: With tumor; Pharmaceutical treatment mitotane indicator: Yes; Clinical status within 3 mths surgery: Biochemical Evidence of Disease.
- Primary pathology: Submitted tumor site: Adrenal; Histologic diagnosis: Adrenocortical carcinoma- Usual Type; Ct scan preop results: Yes; Mitoses per 50 hpf: 90.
- Primary pathology, Weiss assessment report, Weiss assessment categories: Nuclear grade III IV: Nuclear Grade III or IV Present; Mitotic rate: Mitotic Rate > 5/50 HPF Present; Atypical mitotic figures: Atypical Mitotic Figures Present; Cytoplasm presence less than equal 25 percent: Cytoplasm presence <= 25% Present; Diffuse architecture: Diffuse Architecture Present; Necrosis: Necrosis Present; Weiss venous invasion: Venous Invasion Present; Sinusoid invasion: Sinusoid Invasion Present; Invasion of tumor capsule: Invasion of Tumor Capsule Present.
- Primary pathology, Excess adrenal hormone history types: History adrenal hormone excess: Cortisol.
- Primary pathology, Germline genotype testing report: Molecular studies others performed: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 562 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 562 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 72 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-OR-A5JM-01A-11D-A29H-01): tumor purity 0.97, ploidy 3.05, whole-genome doublings 1.
